Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A11C, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A11C-01A (Primary Tumor).

[page 1 of 4]
100-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0 1/24/11 *hw*

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

.1 A2 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14

C15

Right lobe liver (2890.0 grams, 24.3 x 22.0 x 13.3 cm), a pericholedochal lymph node (2.1 x 1.1 x 0.8 cm), and gallbladder (9.2 x 4.4 x 2.1 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 22.0 x 15.3 x 12.8 cm mass in the right lobe of noncirrhotic liver. The surgical margins are free of tumor by a minimum of 1.1 cm. A large (10.3 x 7.4 x 5.5 cm) subcapsular hematoma is also present.

Lymph node, pericholedochal, excision: A single pericholedochal lymph node is negative for tumor.

Gallbladder, cholecystectomy: Mild chronic cholecystitis with cholesterosis and a single benign cystic duct lymph node are identified.

UUID:35CDSB20-BF61-4D28-AC7F-2CDC959382CD

Diagnosis Discrepancy		hw
Primary Tumor Site Discrepancy		hw
HIPAA Discrepancy		hw
Prior Malignancy History		hw
Dual/Synchronous Primary		hw
Case in (circle):	hw	hw

[page 2 of 4]
105-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0 1/24/11 hr

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

A1 A2 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14
C15

Right lobe liver (2890.0 grams, 24.3 x 22.0 x 13.3 cm), a
pericholedochal lymph node (2.1 x 1.1 x 0.8 cm), and gallbladder
(9.2 x 4.4 x 2.1 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 3 (of 4) hepatocellular
carcinoma forming a 22.0 x 15.3 x 12.8 cm mass in the right lobe of
noncirrhotic liver. The surgical margins are free of tumor by a
minimum of 1.1 cm. A large (10.3 x 7.4 x 5.5 cm) subcapsular
hematoma is also present.

Lymph node, pericholedochal, excision: A single pericholedochal
lymph node is negative for tumor .

Gallbladder, cholecystectomy: Mild chronic cholecystitis with
cholesterolosis and a single benign cystic duct lymph node are
identified .

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)* **Patient key:**

Surgical pathology number:

Surgery Date:

MACROSCOPIC

Specimen Type

- ☒ Right lobectomy
- ☐ Extended right lobectomy
- ☐ Medial segmentectomy
- ☐ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☐ Other (specify): _____
- ☐ Not specified

Focality

- ☒ Solitary (specify location): right lobe
- ☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 22.0 cm

*Additional dimensions: 15.3 x 12.8 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☒ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☒ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: 2

Number involved: 0

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☒ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 11.0 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☒ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☒ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☐ Other (specify): _____

Source: NCI Genomic Data Commons file ea92df9a-d919-4e20-9fc2-64e1f38ff12b (TCGA-DD-A11C.35CD5B20-BF61-4D28-AC7F-2CDC959382CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).